Somatic mutation profile of tumor specimen 0DIR3X from CCDI case PBBVZZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 6.8 years (2,477 days).
Specimen 0DIR3X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 949677a3-2df6-4b9f-b0d2-44fa87229e38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIQZP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cc7f937-a35a-41af-b836-6dba668a6403

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 148/449 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772682511, COSV60113444; called by muse, mutect2, varscan2
- CPEB4 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 144/468 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54171505; called by muse, mutect2, varscan2
- KLHL6 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 95/260 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773405975, COSV58064252; called by muse, mutect2, varscan2
- ROBO2 | c.2974del p.T992Hfs*39 | Frame Shift Del (DEL) | VAF 163/498 reads (33%) | catalogued as COSV100164851; called by mutect2, pindel, varscan2
- WDHD1 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 98/248 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DYNLT3 | c.30+81G>A | Intron (SNP) | VAF 59/87 reads (68%) | called by muse, mutect2, varscan2
